Somatic mutation profile of tumor specimen ALCH-AE79-TTP1-A (aliquot ALCH-AE79-TTP1-A-1-0-D-A596-36) from ALCHEMIST case ALCH-AE79, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 50.8 years (18,549 days).
Specimen ALCH-AE79-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8bf8b3d-dace-420b-a4de-a334bea34863.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE79-NB1-A (Blood Derived Normal), aliquot ALCH-AE79-NB1-A-2-0-D-A596-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53ee0641-d822-45e8-9ac9-898b85a88228

The open-access MAF lists 40 somatic variants for this specimen: 26 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 13, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 15/222 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, mutect2
- ABHD1 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 19/412 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV53207303; called by muse, mutect2
- CPNE7 | c.307A>G p.S103G | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1163824912; called by muse, mutect2
- DACH2 | c.700A>G p.M234V | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs1287065665; called by muse, mutect2
- KCNN3 | c.1371C>G p.I457M | Missense Mutation (SNP) | VAF 40/528 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); catalogued as COSV99677410; called by muse, mutect2
- MEN1 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 22/524 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.138); catalogued as rs1471493357, CD077418, CM077294, CX002575; ClinVar: uncertain significance; called by muse, mutect2
- PCDHB15 | c.605G>T p.R202L | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs782402588, COSV50858060; called by muse, mutect2
- PLA1A | c.206G>C p.G69A | Missense Mutation (SNP) | VAF 44/658 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV56331095; called by muse, mutect2
- PLXNA1 | c.3521G>A p.R1174Q | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.686); catalogued as rs1282669146; called by muse, mutect2
- SNTG2 | c.1371G>C p.K457N | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.276); catalogued as COSV57999420; called by muse, mutect2
- ALDH3A2 | c.584A>G p.E195G | Missense Mutation (SNP) | VAF 26/902 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.297); called by muse, mutect2
- ANKDD1B | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.488); called by muse, mutect2
- ANKRD11 | c.7282G>A p.E2428K | Missense Mutation (SNP) | VAF 32/882 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2
- BCL6 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 11/248 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.027); called by muse, mutect2
- CCT7 | c.749A>C p.K250T | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- CDH8 | c.788C>T p.T263I | Missense Mutation (SNP) | VAF 21/480 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2
- CNNM4 | c.866C>A p.A289D | Missense Mutation (SNP) | VAF 20/431 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CROCC2 | c.1322G>T p.R441L | Missense Mutation (SNP) | VAF 12/338 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- DCAF4L2 | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 22/479 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.437); called by muse, mutect2
- EPM2A | c.292T>A p.S98T | Missense Mutation (SNP) | VAF 28/625 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.072); called by muse, mutect2
- GRM1 | c.2428T>C p.Y810H | Missense Mutation (SNP) | VAF 26/978 reads (3%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2
- MCIDAS | c.658C>G p.R220G | Missense Mutation (SNP) | VAF 21/421 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2
- PRAMEF17 | c.1018C>T p.L340F | Missense Mutation (SNP) | VAF 24/726 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLAIN2 | c.1564A>G p.T522A | Missense Mutation (SNP) | VAF 28/686 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.244); called by muse, mutect2
- TPR | c.4486C>T p.Q1496* | Nonsense Mutation (SNP) | VAF 19/212 reads (9%) | called by muse, mutect2
- WASHC4 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 18/480 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- ABL1 | c.3232A>C p.R1078= | Silent (SNP) | VAF 21/585 reads (4%) | called by muse, mutect2
- ASB7 | c.468C>T p.L156= | Silent (SNP) | VAF 39/742 reads (5%) | catalogued as rs549056141; called by muse, mutect2
- CATSPERB | c.450A>G p.L150= | Silent (SNP) | VAF 12/310 reads (4%) | catalogued as COSV56426315; called by muse, mutect2
- CD8A | c.27C>T p.L9= | Silent (SNP) | VAF 20/472 reads (4%) | called by muse, mutect2
- ERCC3 | c.39A>G p.K13= | Silent (SNP) | VAF 20/500 reads (4%) | called by muse, mutect2
- FAM47B | c.1455T>C p.F485= | Silent (SNP) | VAF 14/310 reads (5%) | called by muse, mutect2
- MAGED1 | c.1290C>T p.P430= | Silent (SNP) | VAF 17/419 reads (4%) | catalogued as rs184387756; called by muse, mutect2
- PLD1 | c.2235C>G p.L745= | Silent (SNP) | VAF 12/284 reads (4%) | called by muse, mutect2
- SLITRK1 | c.354C>A p.I118= | Silent (SNP) | VAF 32/708 reads (5%) | catalogued as rs1310801355, COSV65676960; called by muse, mutect2
- TEX13C | c.1305G>T p.G435= | Silent (SNP) | VAF 20/367 reads (5%) | called by muse, mutect2
- USH2A | c.3216C>T p.L1072= | Silent (SNP) | VAF 22/442 reads (5%) | catalogued as COSV56387130; called by muse, mutect2
- VAX1 | c.195C>T p.S65= | Silent (SNP) | VAF 22/484 reads (5%) | catalogued as rs1564972367; called by muse, mutect2
- WARS2 | c.873G>C p.V291= | Silent (SNP) | VAF 18/490 reads (4%) | called by muse, mutect2
- PLEKHA8P1 | n.1291G>T | RNA (SNP) | VAF 17/617 reads (3%) | called by muse, mutect2
